Gene-level copy-number profile of tumor specimen TCGA-A2-A4S3-01A from TCGA case TCGA-A2-A4S3, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.6 years (21,762 days).
Specimen TCGA-A2-A4S3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.c3744133-3c3e-4f65-b3cc-3ddadc486384.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A4S3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9ab56272-a8d5-4d75-ab32-b0ebfe231d37

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 23,860; copy number 2: 30,665; copy number 3: 3,480; copy number 4: 509; copy number 5: 360; copy number 6: 429; copy number 7: 313; copy number 8: 36; copy number 9: 156.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A4S3-01A-21D-A25N-01): tumor purity 0.58, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:58,660,424–58,692,018, 1 gene (within-gene range 0–2): IGBP1P2.
- chr17:58,675,286–58,735,611, 4 genes: AC011195.1, RNU1-52P, RNVU1-34, RAD51C.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,294 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:36,378,069–37,095,390, 9 genes, copy number 6: AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4.
- chr8:38,728,186–42,737,407, 80 genes, copy number 5–6 (broad region; genes not listed).
- chr8:49,046,652–59,456,010, 144 genes, copy number 6 (broad region; genes not listed).
- chr8:60,185,412–98,036,724, 570 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:99,013,266–99,877,580, 1 gene, copy number 6 (within-gene range 4–6): VPS13B.
- chr8:99,340,305–104,256,094, 122 genes, copy number 6 (broad region; genes not listed).
- chr8:104,339,087–104,356,689, 1 gene, copy number 6: DCSTAMP.
- chr8:107,899,316–108,489,196, 7 genes, copy number 6 (within-gene range 4–6): RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2.
- chr8:115,408,496–116,403,757, 6 genes, copy number 5 (within-gene range 4–5): TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1.
- chr14:25,357,764–28,823,817, 30 genes, copy number 6–7 (within-gene range 4–7): OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282.
- chr17:61,942,605–63,472,093, 50 genes, copy number 5: MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA, Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7, METTL2A, TLK2, AC008026.1, AC008026.3, AC080038.2, AC080038.1, MRC2, Y_RNA, AC080038.3, RNU6-446P, AC005821.1, MARCHF10, AC005821.2, MARCHF10-DT, PRELID3BP3, AC005972.3, MIR633, TRMT112P3, AC005972.1, AC005972.2, TANC2, AC006270.2, AC006270.1, DNAJB6P8, AC015923.1, AC005828.2, AC005828.7, AC005828.1, AC005828.3, AC005828.6, AC005828.4, CYB561, AC005828.5, PPIAP55.
- chr17:70,017,324–78,846,868, 273 genes, copy number 5 (broad region; genes not listed).
- chr17:78,855,478–78,855,844, 1 gene, copy number 5: AC022966.1.

Autosomal genes at a single copy (total copy number 1): 21,491. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
